HCMI case HCM-CSHL-0853-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/a7364c7c-cc66-468d-8a6e-11cc58adf3d6

Demographics
Sex at birth: female; Days to birth: -19,345 days (53.0 years before the index date); Year of birth: 1967.

Diagnoses (5)
1. Serous surface papillary carcinoma (the primary disease): ICD-O-3 morphology code: 8461/3; ICD-10 code: C56; Tissue or organ of origin: Ovary; Classification of tumor: primary; AJCC staging edition: 8th; FIGO stage: Stage IIIC; Tumor grade: High Grade; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Abdomen / Adnexa / Omentum / Sigmoid colon / Transverse colon.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C78.5; Tissue or organ of origin: Ovary; Site of resection or biopsy: Sigmoid colon; Classification of tumor: metastasis; Sites of involvement: Omentum / Abdomen / Adnexa / Transverse colon.
3. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Uterine adnexa; Classification of tumor: metastasis; Sites of involvement: Omentum / Abdomen / Transverse colon / Sigmoid colon.
4. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Sites of involvement: Omentum / Adnexa / Transverse colon / Sigmoid colon.
5. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Sites of involvement: Abdomen / Adnexa / Sigmoid colon.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Uterine adnexa; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Sigmoid colon; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Follow-up contact recording only the day: day 35.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 108 kg; Height: 173 cm; BMI: 36.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0853-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0853-C56-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 48; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0853-C56-06A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 67; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0853-C56-07A: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0853-C56-07A-01-S2-HE: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 74; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0853-C56-07A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 87; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0853-C56-07B: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0853-C56-07B-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0853-C56-07B-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 76; Percent normal cells: 55; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0853-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0853-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
- Sample HCM-CSHL-0853-C56-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
- Samples HCM-CSHL-0853-C56-85F, HCM-CSHL-0853-C56-85G (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
